Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A48D, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A48D-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

DOB:

Age:

Gender: M

Order Group:

Ident

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

RIGHT RENAL MASS, PARTIAL NEPHRECTOMY:

- Papillary renal cell carcinoma, type 2.
- Fuhrman nuclear grade 3.
- Tumor size: 4.2 cm.
- Tumor limited to kidney.
- Surgical margins negative.

ICD-0-3
Carcinoma, papillary renal cell
8260/3

Site: Kidney, NOS C64.9

hw
9/27/12

PATHOLOGIC TUMOR STAGING SYNOPSIS (RIGHT KIDNEY):

Type and grade: Papillary renal cell carcinoma, type 2, Fuhrman nuclear grade 3.
Primary tumor: pT1b.
Regional lymph nodes: pNX.
Distant metastasis: N/A.
Pathologic stage: I.
Lymphovascular invasion: Not identified.
Margin status: R0, negative.

Kidney Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol,

Case #:

Printed:

Pathology Consultation Report

Page 1

This report continues... (FINAL)

Patient

Page 1 Doc#

[page 2 of 3]
Patient:

Case #:

Procedure:	Partial nephrectomy.
Specimen laterality:	Right.
Tumor size:	4.2 cm.
Tumor focality:	Single focus.
Macroscopic extent of tumor:	Limited to kidney.
Histologic type:	Papillary renal cell carcinoma, type 2.
Sarcomatoid features:	Not identified.
Histologic grade:	Fuhrman nuclear grade 3.
Microscopic tumor extension:	Limited to kidney.
Margins:	R0, negative, tumor 0.3 cm from renal parenchymal margin.
Lymph nodes:	N/A.
Pathologic tumor staging:	
Primary tumor:	pT1b.
Regional lymph nodes:	pNX.
Distant metastasis:	N/A.
Pathologic stage:	I.
Pathologic findings in non-neoplastic kidney:	Mild arteriolonephrosclerosis.

[page 3 of 3]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Mass, right renal mass

Clinical History/Operative Dx:

Right renal

Gross Description:

Single specimen designated as right renal mass. Initially received in the fresh state for possible Oncogenotyping studies is a 50 gram portion of renal tissue, 6.5 x 5.0 x 4.2 cm. The likely deep surgical margin is now marked black. The renal capsular surface includes a discreet amount of Gerota's fascia, and is now over-inked blue.

The specimen is serially sectioned to reveal a well-circumscribed encapsulated appearing tumor mass measuring upwards of 4.2 cm and demonstrating a predominantly delicate, possibly non viable, deep-red, hemorrhagic cut surface. The mass lesion grossly approaches within 0.3 cm of the nearest surgical margin. The grossly uninvolved renal tissue along the deep surgical margin is dusky red and purple. The tumor mass appears grossly confined and abuts the renal capsule.

A representative portion of the tumor mass along with "paranormal" renal tissue is submitted for Oncogenotyping studies. Representative sections/portions of the mass lesion are submitted for routine histology in A1 and A2 (wrapped in filter paper) with the renal capsule/Gerota's fascia represented in A3-A4 and surgical margin and tumor relationship in A5-A8.

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

An intradepartmental consultation with results on

was obtained.

office notified of

Case #:

Printed:

Pathology Consultation Report

Page 3

END OF REPORT (FINAL)

Patient

Page 3 Doc# 1

Source: NCI Genomic Data Commons file 7e5ae492-2e36-4a19-a944-b6dfd6ca747b (TCGA-A4-A48D.8EE9788C-EF35-44D5-8908-C14B5AFA8FAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).